Surgical pathology report (de-identified scan), TCGA case TCGA-ZG-A8QX, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University Medical Center Hamburg-Eppendorf, specimen TCGA-ZG-A8QX-01A (Primary Tumor).

[page 1 of 2]
Histopathological Report

Date of cancer sample procurement:

Date of pathology report:

Patient ID:

ICD-O-3
Adenocarcinoma, NOS 8140/3
Site: Prostate NOS 061.9
Y 3/31/14

Gross description:

1. (Prostate gland): Prostate gland: Weight: 26 g, Volume: 21 ml, Size: 4.2 x 4.3 x 2.6 cm. Adherent seminal vesicles and deferent duct: right side: 2.5 cm, left side: 2.4 cm. The surface is marked with green ink on the right side, blue ink on the left side. On the right recto-lateral surface a 2.5 x 2.5 cm measuring tissue defect marked with yellow ink. On the left recto-lateral surface a 3.2 x 2.4 cm measuring tissue defect marked with yellow ink. Apical peri-urethral a funnel-shaped 1.0 x 1.2 cm measuring tissue defect marked with red ink. Total of the cross sections: 2 cm.
2. (Lymph nodes, right side): 4.5 x 1.3 x 1.2 cm measuring adipose tissue containing four nodes measuring up to 4.5 cm.
3. (Lymph nodes, left side): 2.2 x 1.3 x 0.7 cm measuring adipose tissue containing three nodes measuring up to 2.2 cm.

Microscopy:

1. Apex right side and left side: Right side 5 tissue blocks, left side 6 tissue blocks (total 11 tissue blocks). 3 cross sections: Right side 8 tissue blocks, left side 8 tissue blocks (total 16 tissue blocks). Basis right side and left side: Right side 5 tissue blocks, left side 7 tissue blocks (total 12 tissue blocks). Seminal vesicles right side and left side: Right side 5 tissue blocks, left side 4 tissue blocks (total 9 tissue blocks). Deferent ducts right side and left side: Right side 1 tissue block, left side 1 tissue block (total 2 tissue blocks).
2. 9 tissue blocks.
3. 5 tissue blocks.

Diagnosis:

1. (Prostate gland): Moderately differentiated prostatic adenocarcinoma, Gleason 3+3=6. Tumor involves both lobes. Maximum tumor diameter: 17 mm. No perineural invasion. No tumor infiltration into prostatic adipose tissue. Negative surgical margin (circumference and peri-urethral)

Remaining prostatic tissue with small foci prostatic intraepithelial neoplasia (high grade PIN) and signs of myoglandular hyperplasia of the prostate. Urothelium of the prostatic urethra without dysplasia. Tumor-free seminal vesicles and deferent ducts on both sides.

[page 2 of 2]
2. (Lymph nodes, right side): Nine tumor-free lymph nodes (0/9).
3. (Lymph nodes, left side): Nine tumor-free lymph nodes (0/9).

Tumor classification

(in consideration of the intraoperative frozen-section, parallel report and immunohistochemical analyses):

pT2c, Gleason 3+3=6, maximum tumor diameter: 17 mm, tumor volume approx. 2.2 ml, pN0 (0/18), L0, V0, R0

Comments:

In the intraoperative frozen-section examination of the recto-lateral circumference tumor was identified on both sides with negative surgical margins on both sides.

Immunohistochemical analyses (D2-40, CD31) were performed on tissue blocks 2E and 2G to exclude lymphatic and venous invasion.

One macroscopic image for tumor mapping.

Source: NCI Genomic Data Commons file 269828b7-f7bb-4eab-8822-a8d434ffdf00 (TCGA-ZG-A8QX.153CAD0D-4566-4BC2-B33D-FF1B44BA8E2B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).